Somatic mutation profile of tumor specimen ALCH-B25C-TTP1-A (aliquot ALCH-B25C-TTP1-A-1-0-D-A774-36) from ALCHEMIST case ALCH-B25C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.7 years (24,723 days).
Specimen ALCH-B25C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ac02006-64dc-41d3-9088-d9073f085bed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B25C-NB1-A (Blood Derived Normal), aliquot ALCH-B25C-NB1-A-1-0-D-A774-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e06d43e5-e203-4cbc-b981-df4ff80fee73

The open-access MAF lists 285 somatic variants for this specimen: 182 protein-altering or splice-affecting, 65 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 65, Intron 15, RNA 9, Nonsense Mutation 8, 5'UTR 7, 3'UTR 4, Splice Site 3, 5'Flank 2, Frame Shift Del 2, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 51/267 reads (19%) | hotspot (GDC flag); catalogued as rs864622636, CM023895, COSV58683786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 47/341 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 46/434 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs754236392; called by muse, mutect2, varscan2
- ALPK2 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs972401240; called by muse, mutect2
- ARFGAP3 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); catalogued as COSV99605477; called by muse, mutect2
- ASCC3 | c.5225G>T p.G1742V | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1376852199; called by muse, mutect2, varscan2
- CD163 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV63131874; called by muse, mutect2
- CEMIP2 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65489532; called by muse, mutect2
- CNTNAP2 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 36/546 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs368487049; ClinVar: uncertain significance; called by muse, mutect2
- COL22A1 | c.4876C>T p.P1626S | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV57328325; called by muse, mutect2
- DIS3L | c.2309T>C p.L770P (on ENST00000319212 / NM_001143688.3; = p.L687P on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/287 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs1284539039; called by muse, mutect2, varscan2
- DNASE1L2 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs747860937; called by muse, mutect2, varscan2
- EIF2AK1 | c.1212G>T p.E404D | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs1184517750, COSV99551692; called by muse, mutect2, varscan2
- EMILIN3 | c.473C>A p.P158H | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV60038250; called by muse, mutect2, varscan2
- EVX2 | c.340A>C p.M114L | Missense Mutation (SNP) | VAF 60/426 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs748932110; called by mutect2, varscan2
- FAT4 | c.13196G>T p.G4399V | Missense Mutation (SNP) | VAF 40/477 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100627671; called by muse, mutect2
- FLRT2 | c.814T>G p.F272V | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100420951; called by muse, mutect2, varscan2
- FLT1 | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.438); catalogued as COSV56722865; called by muse, mutect2
- FNDC1 | c.5386G>A p.V1796M | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182867913, COSV99796685; called by muse, mutect2, varscan2
- GPR83 | c.410G>T p.W137L | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.9); catalogued as COSV54717461; called by muse, mutect2
- ITGA10 | c.2990G>A p.G997E | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.534); catalogued as COSV100994664; called by muse, mutect2
- KATNIP | c.2943C>G p.I981M | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99851702; called by muse, mutect2
- KCNN1 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV55839557; called by muse, mutect2, varscan2
- KERA | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.593); catalogued as CM000721; called by muse, mutect2
- KLHL17 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 56/448 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs750664001; called by muse, mutect2, varscan2
- KLK3 | c.606G>C p.W202C | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs191588971; called by muse, mutect2, varscan2
- KMT2D | c.11794C>T p.Q3932* | Nonsense Mutation (SNP) | VAF 46/286 reads (16%) | catalogued as CM146870, COSV104396472; called by muse, varscan2
- LGALS9 | c.882del p.R296Efs*38 (on ENST00000395473 / NM_009587.3; = p.R264Efs*38 on NM_002308.4) | Frame Shift Del (DEL) | VAF 63/482 reads (13%) | catalogued as COSV56348210; called by mutect2, pindel, varscan2
- LRFN5 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs776013298, COSV99983074; called by muse, mutect2
- MAP3K2 | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV61295835; called by muse, mutect2, varscan2
- MRPL30 | c.476A>T p.H159L | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs770941810; called by muse, varscan2
- MSANTD3 | c.768A>C p.Q256H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV58495657; called by muse, mutect2, varscan2
- MTMR4 | c.2113C>T p.L705F | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT tolerated, low confidence (0.71); PolyPhen possibly damaging (0.567); catalogued as COSV60204782; called by muse, mutect2, varscan2
- MUC16 | c.27266C>A p.T9089K | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV67494900; called by muse, mutect2, varscan2
- MUC5AC | c.13777C>G p.P4593A | Missense Mutation (SNP) | VAF 23/355 reads (6%) | SIFT tolerated (0.12); catalogued as rs1369123141; called by muse, mutect2
- MYBPC1 | c.1225G>A p.D409N (on ENST00000550270 / NM_206820.2; = p.D434N on NM_002465.4) | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62258149; called by muse, mutect2, varscan2
- OR10Z1 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63524954; called by muse, mutect2, varscan2
- OR4C11 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs78637271; called by muse, mutect2
- OR5L2 | c.78C>A p.C26* | Nonsense Mutation (SNP) | VAF 15/205 reads (7%) | catalogued as rs1455375807; called by muse, mutect2
- PDRG1 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs780722451; called by muse, mutect2, varscan2
- PIP5K1B | c.1012A>T p.R338W | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1186325790; called by muse, mutect2
- POTEE | c.336C>A p.S112R | Missense Mutation (SNP) | VAF 68/676 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.451); catalogued as rs569338535; called by muse, mutect2, varscan2
- PRKCG | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 20/297 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.058); catalogued as rs762479860; called by muse, mutect2
- PTPRT | c.2780C>T p.S927F | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs866132388, COSV62009437; called by muse, mutect2
- PUM1 | c.3455G>C p.R1152P | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57085208; called by muse, mutect2
- RALGDS | c.1487G>C p.R496P | Missense Mutation (SNP) | VAF 64/395 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64426981, COSV64429833; called by muse, mutect2, varscan2
- RASA1 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 28/190 reads (15%) | catalogued as COSV57196502; called by muse, varscan2
- RCOR2 | c.991C>A p.R331S | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56850305; called by muse, mutect2, varscan2
- RUNX1T1 | c.454G>T p.V152F (on ENST00000265814 / NM_001198628.1; = p.V125F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150721308; called by muse, mutect2, varscan2
- SAMD3 | c.488A>T p.Q163L | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV100148132; called by muse, mutect2, varscan2
- SMOC2 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs373406001; called by muse, mutect2, varscan2
- SNAPC2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs1228423928; called by muse, mutect2
- SPEN | c.9032G>T p.R3011L | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV101005041, COSV65358096; called by muse, mutect2, varscan2
- SVEP1 | c.10504C>T p.P3502S | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373165052; called by muse, varscan2
- TAF4 | c.2818G>T p.V940F | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53343709; called by muse, mutect2, varscan2
- TBC1D17 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | catalogued as COSV55577966; called by muse, mutect2, varscan2
- TBC1D2 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV59786566; called by muse, mutect2
- TBC1D8B | c.1969G>A p.V657M | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52177738; called by muse, mutect2
- TBX4 | c.424C>G p.P142A | Missense Mutation (SNP) | VAF 28/341 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs767009862; called by muse, mutect2
- TG | c.1438G>T p.V480F | Missense Mutation (SNP) | VAF 28/540 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs1166533435; called by muse, mutect2
- TPBG | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.112); catalogued as rs778997503; called by muse, mutect2, varscan2
- ZBTB46 | c.1531G>C p.G511R | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs560993615, COSV55509631; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1377952064; called by muse, mutect2, varscan2
- ZNF516 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 20/363 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.106); catalogued as rs1480736202, COSV99069440; called by muse, mutect2
- ZNF813 | c.1176C>G p.F392L | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV67177944; called by muse, mutect2
- ZNF91 | c.1537A>G p.T513A | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs879006484, COSV56095582; called by muse, mutect2, varscan2
- ZSWIM2 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.321); catalogued as rs765716604; called by muse, varscan2
- ABCB5 | c.1801G>T p.A601S (on ENST00000404938 / NM_001163941.2; = p.A156S on NM_178559.6) | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2
- AC069544.2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); called by muse, mutect2
- AKAP9 | c.7610T>C p.L2537S (on ENST00000359028; = p.L2513S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- AMER3 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- APC2 | c.6485T>A p.L2162H | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGAP39 | c.2354A>C p.Y785S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C1orf167 | c.3553C>T p.L1185F | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2CD4C | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- CACNB4 | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CAGE1 | c.2100G>T p.E700D (on ENST00000512086; = p.E564D on NM_205864.3) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2
- CCL21 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- CD4 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.106); called by muse, mutect2
- CDC42BPB | c.4115C>T p.A1372V | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CDH24 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 13/144 reads (9%) | called by muse, mutect2
- CDK11A | c.1822G>A p.D608N (on ENST00000378633 / NM_001313896.2; = p.D605N on NM_024011.4) | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP47 | c.6896A>T p.K2299I | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CHIA | c.413A>T p.D138V (on ENST00000343320; = p.D30V on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRNA4 | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 36/455 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CIART | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, varscan2
- CNDP1 | c.651C>A p.F217L | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- CNTNAP5 | c.1483G>T p.D495Y | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2
- COL11A1 | c.2260G>C p.G754R | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL11A1 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 24/597 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2
- CPSF3 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 19/247 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- CSGALNACT1 | c.1529T>C p.L510P | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CSMD3 | c.5395G>A p.V1799M (on ENST00000297405 / NM_001363185.1; = p.V1695M on NM_052900.3) | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CST9L | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- DACT3 | c.302G>A p.S101N | Missense Mutation (SNP) | VAF 22/323 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.806); called by muse, mutect2
- DCX | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMC1 | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- DMRTB1 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH3 | c.11380G>T p.A3794S | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.026); called by muse, mutect2
- DNAH9 | c.12049G>A p.E4017K | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC6 | c.706A>T p.I236F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2
- ECI2 | c.124G>T p.D42Y (on ENST00000380118 / NM_206836.3; = p.D12Y on NM_006117.2) | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EFCAB13 | c.833T>C p.I278T | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- FGF3 | c.620A>T p.Q207L | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FOXJ2 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 34/625 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2
- FSHR | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GATAD1 | c.506A>C p.Q169P | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- GJA5 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 52/578 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.771); called by muse, mutect2
- GON4L | c.2050G>T p.D684Y | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GP6 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- GPR37 | c.1161G>C p.W387C | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR85 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.12); called by muse, mutect2
- GRIN2A | c.1628C>G p.T543S | Missense Mutation (SNP) | VAF 26/431 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- HERC4 | c.2752G>T p.A918S (on ENST00000395198 / NM_022079.3; = p.A910S on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.015); called by muse, mutect2
- HOXA3 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2
- IGHV4-39 | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KDM4A | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2
- KDM4C | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.23); called by muse, mutect2
- KHNYN | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 36/361 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KIAA2026 | c.3052G>C p.V1018L | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAGEB1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 20/300 reads (7%) | called by muse, mutect2
- MED22 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MEIOC | c.2005T>A p.Y669N | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.542); called by muse, varscan2
- METTL24 | c.926G>C p.S309T | Missense Mutation (SNP) | VAF 51/398 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MIA3 | c.4836A>G p.I1612M | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2
- MME | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRC1 | c.660G>T p.W220C | Missense Mutation (SNP) | VAF 44/472 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MSH6 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MUC5B | c.14922T>A p.N4974K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- MYO16 | c.2231T>G p.L744R | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- NCOA2 | c.4177T>C p.S1393P | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- NLRX1 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- NPEPL1 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR10R2 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR4C5 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 20/464 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.195); called by muse, mutect2
- OR5I1 | c.470G>C p.S157T | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.148); called by muse, mutect2
- OSCP1 | c.830A>T p.N277I (on ENST00000356637 / NM_001330493.1; = p.N267I on NM_145047.5) | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.143); called by muse, mutect2
- PCARE | c.854T>A p.V285E | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCDHA1 | c.1634T>A p.L545Q | Missense Mutation (SNP) | VAF 118/793 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHA3 | c.2176C>A p.P726T | Missense Mutation (SNP) | VAF 64/443 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHB11 | c.1651G>C p.V551L | Missense Mutation (SNP) | VAF 95/934 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- PELI2 | c.332del p.P111Lfs*82 | Frame Shift Del (DEL) | VAF 36/333 reads (11%) | called by mutect2, pindel, varscan2
- PKD2L1 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHM1 | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 59/427 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- PLOD3 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PRR36 | c.1613T>C p.L538S | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated (0.47); called by muse, mutect2
- PTER | c.347A>C p.E116A | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, varscan2
- PTPRD | c.5062C>A p.L1688M | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PTPRU | c.2886A>T p.Q962H | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF130 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 16/522 reads (3%) | called by muse, mutect2
- ROBO2 | c.817A>C p.K273Q | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.348); called by muse, mutect2
- RPS7 | c.342A>T p.Q114H | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- SEZ6L | c.1679A>T p.E560V | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- SI | c.4620T>A p.H1540Q | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2
- SLC12A1 | c.2154+1G>T p.X718_splice | Splice Site (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- SLC17A6 | c.659G>T p.C220F | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- SLC18A2 | c.739G>T p.G247W | Missense Mutation (SNP) | VAF 44/402 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35G6 | c.572T>A p.L191Q | Missense Mutation (SNP) | VAF 62/295 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SPTBN4 | c.2803G>T p.G935C | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- STOX1 | c.2285G>T p.G762V | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2
- SYNJ1 | c.3814+1G>T p.X1272_splice | Splice Site (SNP) | VAF 26/172 reads (15%) | called by muse, mutect2, varscan2
- SYNJ1 | c.3814G>T p.G1272C | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TANC2 | c.3484G>T p.A1162S | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2
- TAS2R10 | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBX4 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TGFBR1 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 12/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TIMM23B | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); called by muse, mutect2
- TMEM184A | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMF1 | c.2245-2A>T p.X749_splice | Splice Site (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- TRABD2B | c.928A>G p.R310G | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TRIM9 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TRO | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); called by muse, mutect2
- TTC27 | c.1734A>T p.Q578H | Missense Mutation (SNP) | VAF 29/353 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2
- TTC6 | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- VPS8 | c.4124G>T p.R1375L (on ENST00000625842 / NM_001349294.1; = p.R1373L on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2
- VTN | c.1330T>C p.Y444H | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR92 | c.957G>T p.L319F | Missense Mutation (SNP) | VAF 14/381 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- ZBED9 | c.3311A>G p.Y1104C | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZBTB6 | c.922C>G p.R308G | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF717 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2
- ZNF74 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- ZNF99 | c.1877G>T p.C626F | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.416); called by muse, mutect2
- ADAMTS6 | c.1401G>A p.E467= | Silent (SNP) | VAF 28/201 reads (14%) | called by muse, mutect2, varscan2
- ADGRL4 | c.1677C>T p.T559= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs200284765, COSV66062525; called by muse, mutect2, varscan2
- AGTR1 | c.249A>T p.L83= | Silent (SNP) | VAF 16/229 reads (7%) | called by muse, mutect2
- ALMS1 | c.27G>C p.P9= | Silent (SNP) | VAF 36/305 reads (12%) | catalogued as rs1283224132; called by muse, varscan2
- ARHGAP15 | c.1311C>G p.T437= | Silent (SNP) | VAF 24/322 reads (7%) | called by muse, mutect2
- ARHGEF11 | c.3777G>T p.G1259= | Silent (SNP) | VAF 36/215 reads (17%) | called by muse, mutect2, varscan2
- ASB16 | c.825T>C p.A275= | Silent (SNP) | VAF 13/165 reads (8%) | called by muse, mutect2
- ASPM | c.4326A>G p.Q1442= | Silent (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- ATP2A3 | c.501G>A p.E167= | Silent (SNP) | VAF 11/272 reads (4%) | catalogued as COSV59231118; called by muse, mutect2
- BCOR | c.1008G>T p.S336= | Silent (SNP) | VAF 40/250 reads (16%) | catalogued as rs759420433, COSV60723054; called by muse, mutect2, varscan2
- CDX2 | c.72C>T p.L24= | Silent (SNP) | VAF 25/234 reads (11%) | catalogued as rs367899663; called by muse, mutect2, varscan2
- CHPF | c.78G>A p.L26= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs776800294; called by muse, mutect2, varscan2
- COL6A3 | c.4170G>T p.S1390= | Silent (SNP) | VAF 39/326 reads (12%) | catalogued as COSV55088726; called by muse, mutect2, varscan2
- CX3CR1 | c.291C>A p.L97= | Silent (SNP) | VAF 67/398 reads (17%) | called by muse, mutect2, varscan2
- DCX | c.87C>A p.P29= | Silent (SNP) | VAF 36/241 reads (15%) | called by muse, mutect2, varscan2
- DGKB | c.1335C>T p.P445= | Silent (SNP) | VAF 12/216 reads (6%) | catalogued as rs1215177025; called by muse, mutect2
- EXOC3L4 | c.357C>T p.S119= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV101197571; called by muse, mutect2
- F13B | c.1351T>C p.L451= | Silent (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- GALNS | c.1071G>T p.P357= | Silent (SNP) | VAF 28/275 reads (10%) | catalogued as rs374619390; called by muse, mutect2, varscan2
- GMIP | c.909G>A p.G303= | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- GON4L | c.2049G>T p.L683= | Silent (SNP) | VAF 28/223 reads (13%) | called by muse, mutect2, varscan2
- H4C8 | c.156T>C p.Y52= | Silent (SNP) | VAF 39/287 reads (14%) | catalogued as rs1561771305; called by muse, mutect2, varscan2
- HIF3A | c.399C>T p.I133= (on ENST00000377670 / NM_152795.4; = p.I64= on NM_022462.4) | Silent (SNP) | VAF 21/159 reads (13%) | catalogued as COSV52202669; called by muse, mutect2, varscan2
- ICAM5 | c.1224C>T p.P408= | Silent (SNP) | VAF 13/177 reads (7%) | called by muse, mutect2
- INO80D | c.2109A>G p.Q703= | Silent (SNP) | VAF 12/278 reads (4%) | called by muse, mutect2
- ITPR1 | c.5979C>T p.N1993= (on ENST00000354582; = p.N1938= on NM_002222.7) | Silent (SNP) | VAF 52/347 reads (15%) | called by muse, mutect2, varscan2
- LCT | c.3606C>T p.D1202= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as rs185927524; called by muse, mutect2, varscan2
- LPCAT2 | c.21G>A p.A7= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, varscan2
- LRCH2 | c.1173A>T p.I391= | Silent (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- LRRC15 | c.606C>A p.L202= | Silent (SNP) | VAF 15/288 reads (5%) | called by muse, mutect2
- LSM14A | c.138A>G p.T46= | Silent (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2
- LYPD4 | c.432C>A p.T144= | Silent (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- MC3R | c.855G>T p.L285= | Silent (SNP) | VAF 40/303 reads (13%) | called by muse, mutect2, varscan2
- MCCC1 | c.1413C>G p.L471= | Silent (SNP) | VAF 42/614 reads (7%) | called by muse, mutect2
- MEGF11 | c.2880C>T p.S960= | Silent (SNP) | VAF 132/562 reads (23%) | called by muse, mutect2, varscan2
- MUC16 | c.18324C>A p.V6108= | Silent (SNP) | VAF 24/184 reads (13%) | called by muse, varscan2
- MYH8 | c.2529C>A p.L843= | Silent (SNP) | VAF 64/326 reads (20%) | catalogued as COSV101238658; called by muse, mutect2, varscan2
- NDEL1 | c.696G>A p.P232= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- NOBOX | c.795G>T p.P265= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- OR6P1 | c.879G>A p.R293= | Silent (SNP) | VAF 32/374 reads (9%) | called by muse, mutect2
- OR9G1 | c.99G>T p.V33= | Silent (SNP) | VAF 89/893 reads (10%) | called by muse, mutect2, varscan2
- PCNX4 | c.2814C>T p.Y938= (on ENST00000406854 / NM_001330177.2; = p.Y704= on NM_022495.5) | Silent (SNP) | VAF 24/213 reads (11%) | called by muse, mutect2, varscan2
- PDZRN3 | c.1086C>A p.I362= | Silent (SNP) | VAF 42/392 reads (11%) | catalogued as COSV55216611; called by muse, mutect2, varscan2
- PRRT3 | c.2655A>T p.P885= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- PSMF1 | c.30G>T p.S10= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as rs770803195; called by muse, mutect2, varscan2
- PTPRB | c.5175G>T p.P1725= | Silent (SNP) | VAF 28/266 reads (11%) | called by muse, mutect2
- RCE1 | c.264C>A p.L88= | Silent (SNP) | VAF 15/339 reads (4%) | called by muse, mutect2
- RPL24 | c.165C>T p.Y55= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs747672502; called by muse, varscan2
- RYR1 | c.1023G>A p.G341= | Silent (SNP) | VAF 16/318 reads (5%) | called by muse, mutect2
- SGCE | c.663C>T p.G221= (on ENST00000647096; = p.G185= on NM_003919.3) | Silent (SNP) | VAF 14/240 reads (6%) | catalogued as rs768286622, COSV56016885; called by muse, mutect2
- SLC37A1 | c.1209C>T p.L403= | Silent (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- SLC8A1 | c.2214G>T p.V738= | Silent (SNP) | VAF 41/376 reads (11%) | called by muse, mutect2, varscan2
- THEMIS2 | c.27C>T p.F9= | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.108C>G p.T36= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- TNFRSF8 | c.540C>A p.T180= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs768264174; called by muse, mutect2, varscan2
- TNIK | c.1032G>T p.L344= | Silent (SNP) | VAF 176/468 reads (38%) | called by muse, mutect2, varscan2
- TNRC6B | c.5244G>C p.S1748= (on ENST00000454349 / NM_001162501.2; = p.S1638= on NM_015088.3) | Silent (SNP) | VAF 55/479 reads (11%) | called by muse, mutect2, varscan2
- TOR1AIP1 | c.1527C>G p.V509= | Silent (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- TRIO | c.3192G>T p.L1064= | Silent (SNP) | VAF 24/191 reads (13%) | called by muse, mutect2, varscan2
- TRPC1 | c.549A>G p.V183= (on ENST00000476941 / NM_001251845.2; = p.V149= on NM_003304.4) | Silent (SNP) | VAF 32/347 reads (9%) | catalogued as COSV56424605; called by muse, mutect2
- TTN | c.10212C>A p.A3404= (on ENST00000591111; = p.A3358= on NM_003319.4) | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as COSV100624576; called by muse, mutect2
- WDFY3 | c.2515C>T p.L839= | Silent (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- ZFHX4 | c.696C>A p.L232= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as rs1174959631, COSV99264131; called by muse, mutect2
- ZNF32 | c.195A>G p.L65= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as rs1360368000; called by muse, mutect2
- ZNF524 | c.363G>T p.R121= | Silent (SNP) | VAF 23/205 reads (11%) | called by muse, mutect2, varscan2
- AC022182.2 | n.127C>G | RNA (SNP) | VAF 32/328 reads (10%) | called by muse, mutect2
- AC073348.1 | n.219G>A | RNA (SNP) | VAF 18/259 reads (7%) | catalogued as rs1275510812; called by muse, mutect2
- ADAM10 | c.207-10754A>T | Intron (SNP) | VAF 68/286 reads (24%) | called by muse, mutect2, varscan2
- ADAM10 | c.207-10755G>A | Intron (SNP) | VAF 65/279 reads (23%) | catalogued as COSV53051526; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821525 G>A | 3'Flank (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- AMPH | c.1182+349T>A | Intron (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
- CCBE1 | c.*19C>T | 3'UTR (SNP) | VAF 24/304 reads (8%) | catalogued as rs376780422; ClinVar: uncertain significance; called by muse, mutect2
- CELF3 | c.229-9C>T | Intron (SNP) | VAF 46/323 reads (14%) | called by muse, mutect2, varscan2
- CGB7 | c.-856G>T | 5'UTR (SNP) | VAF 19/99 reads (19%) | called by muse, mutect2, varscan2
- CYP27A1 | c.*1G>C | 3'UTR (SNP) | VAF 50/446 reads (11%) | called by muse, mutect2, varscan2
- DNAJC19 | c.-47G>C | 5'UTR (SNP) | VAF 35/764 reads (5%) | called by muse, mutect2
- DPF1 | c.676+281G>C | Intron (SNP) | VAF 26/245 reads (11%) | catalogued as rs780913902; called by muse, mutect2, varscan2
- DPP6 | c.627+21024G>T | Intron (SNP) | VAF 49/306 reads (16%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.12276-33G>T | Intron (SNP) | VAF 65/477 reads (14%) | called by muse, mutect2, varscan2
- EPOR | c.586-28G>T | Intron (SNP) | VAF 37/294 reads (13%) | catalogued as rs1193125352; called by muse, mutect2, varscan2
- GDAP1 | chr8:74350396 G>T | 5'Flank (SNP) | VAF 28/474 reads (6%) | called by muse, mutect2
- GVINP1 | n.3585G>T | RNA (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- GYG1 | c.-52T>C | 5'UTR (SNP) | VAF 58/750 reads (8%) | called by muse, mutect2
- HSP90AB3P | n.568C>T | RNA (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- KIF28P | n.2493C>A | RNA (SNP) | VAF 28/274 reads (10%) | called by muse, varscan2
- KNOP1P1 | n.152C>T | RNA (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- NGEF | c.-189C>A | 5'UTR (SNP) | VAF 41/388 reads (11%) | called by muse, mutect2, varscan2
- OR2W5 | n.929C>A | RNA (SNP) | VAF 41/326 reads (13%) | called by muse, mutect2, varscan2
- OR4C4P | n.202T>C | RNA (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- OR9Q1 | c.-15+53174G>A | Intron (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- PDIA6 | c.-28G>A | 5'UTR (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2, varscan2
- PEG10 | c.*780A>G | 3'UTR (SNP) | VAF 22/225 reads (10%) | called by muse, mutect2
- POU1F1 | c.-36C>A | 5'UTR (SNP) | VAF 32/287 reads (11%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.706+140A>T | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- SKA2 | chr17:59155190 G>A | 5'Flank (SNP) | VAF 79/508 reads (16%) | catalogued as rs754182359; called by muse, mutect2, varscan2
- TBCE | c.644+33G>C | Intron (SNP) | VAF 11/106 reads (10%) | called by muse, varscan2
- TMEM18 | c.58-504C>G | Intron (SNP) | VAF 15/322 reads (5%) | called by muse, mutect2
- TNNI3 | c.372+41G>T | Intron (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- TNRC18 | c.187+317A>T | Intron (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- UGT2B27P | n.1510G>T | RNA (SNP) | VAF 55/640 reads (9%) | called by muse, mutect2
- WASHC4 | c.-44C>G | 5'UTR (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2
- XIRP2 | c.*1472G>C | 3'UTR (SNP) | VAF 24/255 reads (9%) | called by muse, mutect2
- ZNF880 | c.269-4379A>T | Intron (SNP) | VAF 12/149 reads (8%) | called by muse, mutect2
